Surgical pathology report (de-identified scan), TCGA case TCGA-AG-3609, project TCGA-READ (Rectum Adenocarcinoma), tissue source site Indivumed, specimen TCGA-AG-3609-01A (Primary Tumor).

Diagnosis:

Resection material from rectosigmoid colon with inclusion of an ulcerated, moderately differentiated adenocarcinoma of the colorectal type 4.5 cm from the aboral resection margin and with infiltration of the perirectal fatty tissue and four regional lymph node metastases. Tumor-free circumferential resection margin. Tumor-free colon resection margins. Tumor-free mesenteric resection margin.

Tumor stage: pT3 pN2 (4/42) pMX; G2, L1, V0, locally R0.

Source: NCI Genomic Data Commons file f722a444-4950-4640-a2fa-54b7bb67f08b (TCGA-AG-3609.C763C52E-204F-4986-A008-91C0082FE25A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).